Surgical pathology report (de-identified scan), TCGA case TCGA-YZ-A982, project TCGA-UVM (Uveal Melanoma), tissue source site The Ohio State University, specimen TCGA-YZ-A982-01A (Primary Tumor).

[page 1 of 3]
Facility
Name

Result Information

Status
Edited Result - FINAL

Provider Status
Reviewed

[REDACTED] MD on
[REDACTED] MD on
[REDACTED] MD on

Observation Date and Time

Entry Date

Result Narrative

Surgical Pathology Report

Patient Name: [REDACTED]
Accession #: [REDACTED]
Med. Rec #: [REDACTED]
Submitting Physician: [REDACTED]

--- Clinical History ---

Malignant neoplasm of choroid [190.6], serous retinal detachment of right eye [361.2].

ADDENDA:

Addendum added:

---Final Pathologic Diagnosis---

- A. Right eye, enucleation:
- Ciliochoroidal malignant melanoma, see comment
- Angle closure
- Retinal detachment
- Cataract

SYNOPTIC REPORT FOR UVEAL MELANOMA

UVEAL MELANOMA:

Procedure: Enucleation
Specimen Size
For Enucleation
Anteroposterior diameter: 24 mm
Horizontal diameter: 24 mm
Vertical diameter: 23 mm
Length of optic nerve: 4 mm
Diameter of optic nerve: 5 mm

ICD-O-3

Melanoma, spindle cell NOS
8772/3

Date: (R) Page NOS 69.9

JW 3/12/14

[page 2 of 3]
Specimen Laterality: R
Tumor Site (macroscopic examination/transillumination: not performed
Tumor Basal Size on Transillumination: not performed
Tumor Size After Sectioning
Base at cut edge: tumor fills e of globe (gross): same (from slide)
Height at cut edge: 18 mm
Tumor Location After Sectioning
Distance from anterior edge of tumor to limbus at cut edge: <1 mm
Distance of posterior margin of tumor base from edge of optic disc: 0 mm
Tumor Involvement of Ocular Structures: choroid, ciliary body
Growth Pattern Solid
Histologic Type: Spindle cell melanoma (greater than 90% spindle cells)
Histologic Grade (pG): pG1
Microscopic Tumor Extension
Tumor Location
Anterior margin between equator and iris
Posterior margin between disc and equator
Scleral Involvement: None
Margins
No melanoma at margins
Pathologic Staging (pTNM) pT4b NX MX
Additional Pathologic Findings (select all that apply)
Mitotic rate (number of mitoses per 40X objective with a field area of 0.152 mm²): 6/40 high power fields
Microvascular patterns: negative
Vascular invasion (tumor vessels or other vessels): negative
Degree of pigmentation: moderate
Inflammatory cells/tumor infiltrating lymphocytes: negative
Drusen: present
Retinal detachment: positive
Invasion of Bruch's membrane: negative
Nevus: negative
Hemorrhage: negative
Neovascularization: negative
Other: FISH results are positive for monosomy 3 and cmyc (see separate report)
Comment(s): PAS stain on block Alwas used to evaluate for possible vascular mimicry patterns

The above synoptic report complies, in slightly modified form, with the guidelines of the College of American Pathologists Protocols and the AJCC Cancer Staging Manual, 7th edition, 2010, for the reporting of cancer specimens.

Electronically Signed By

---Addendum Report---

Cytogenetics Report:

Status: Signed Out

Cytogenetics Case Number:

[REDACTED]

[REDACTED]

[page 3 of 3]
Karyotype:
No Dividing Cells

Interpretation:

This is a soft tissue mass [REDACTED] from the right eye of a patient sent for cytogenetic. There were no dividing cells in this sample; therefore cytogenetic diagnosis was not possible. FISH analyses on this sample were positive for gains the chromosome 3 centromere and of CMYC.

Electronically Signed Out By
M.D.

Addendum

Status: Signed Out

The FISH result in the synoptic report was given as monosomy 3, but has been reported (see FISH report) as gains in chromosome 3, an unusual finding.

---SPECIMEN(S) RECEIVED:---

Neuropath, Eye, enucleation/evisceration

---GROSS DESCRIPTION:---

The specimen is received in one properly labeled container with the patient's name and accession number.

A. The specimen is designated "right eye" and consists of an intact globe that is 24.0 mm from anterior to posterior, 24.0 mm in vertical dimension and 23.0 mm in height. The cornea is 11.0 mm in vertical dimension and 12.0 mm in horizontal dimension. Upon sectioning, there is a gray-black, rubbery mass that occupies three-fourths of the globe. The optic nerve stump is 0.4 cm in length x 0.5 cm in diameter.

Summary of Cassettes: A1-3, trisected globe, submitted sequentially

Source: NCI Genomic Data Commons file 719bac86-1642-4739-8ce8-2699a562d11d (TCGA-YZ-A982.6D118D76-61C0-4643-A525-53E3313C149D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).